Surgical pathology report (de-identified scan), TCGA case TCGA-CS-5396, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-5396-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right frontal Brain tumor (excision): anaplastic oligodendroglioma, grade III (WHO scale), see microscopic description, see note
2. Right frontal brain tumor (excision): anaplastic oligodendroglioma, grade III (WHO scale), see microscopic description, see note

Comment:

The proliferation index is within the expected range for an anaplastic oligodendroglioma. [REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material. FISH analysis for the 1p/19q deletion that is characteristic of many oligodendrogliomas is pending and when completed, a separate report will be issued.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

Specimen #1 contains areas of classic oligodendroglioma but no anaplasia. Foci of anaplasia are present in specimen #2 (slides 2A and 2B) and include a significantly elevated mitotic rate, microvascular proliferation, and necrosis. The findings are diagnostic of an anaplastic oligodendroglioma, grade III (WHO scale).

Immunohistochemistry for the proliferation antigen Ki67 was performed as follows: three 250 x 250 micron fields were counted and the percentage of labeled nuclei determined. Over 1000 cells were counted.

[page 2 of 5]
[REDACTED]

The proliferation index ranged from 12.3% to 18% with an overall average of 16%.

Frozen Section Diagnosis:

1. Right frontal tumor: Neoplasm present. Final diagnosis deferred.

[REDACTED]

Clinical History and Diagnosis:

Right frontal mass

Source of Specimen:

1: Right frontal tumor

2: Right frontal tumor

Gross Description:

[REDACTED]

1. Right frontal tumor: Received fresh for frozen section consultation in a container labeled with the patient's name and "#1 right frontal tumor consistent with oligodendroglioma" are multiple fragments of soft, red-tan tissue measuring 3.0 x 2.5 x 1.0 cm in aggregate. Touch preparations and frozen section analysis are performed on approximately 20% of the specimen. The specimen is entirely submitted in eight cassettes for routine processing.

2. Right frontal tumor: Received in a specimen container labeled with the patient's name and "#2 right frontal tumor with calcification" are multiple fragments of tan-white soft tissue that is diffusely hemorrhagic and measures 5.5 x 5.0 x 2.0 cm in aggregate. Sectioning reveals tan-white cut surfaces and diffuse calcification. Representative sections are submitted in 6 cassettes.

Histology Laboratory

[REDACTED]

[page 3 of 5]
[REDACTED]

[REDACTED] 1: Right frontal tumor

1p - FISH

MOLECULAR [REDACTED]

KI 67

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. [REDACTED]
[REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.
[REDACTED] [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]
[REDACTED].

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 4 of 5]
[REDACTED]

[REDACTED]

MEDICAL GENETICS REPORT

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENT IN-SITU HYBRIDIZATION (FISH)

RESULT: Positive for the deletion of 1p
Positive for the deletion of 19q

1p36/1q24

Number of Nuclei scored: 200

Ratio of 1p/1q: 0.59

% cells with del 1p: 71%

19q13/19p13

Number of Nuclei scored: 200

Ratio of 19q/19p: 0.61

% cells with del 19q: 71.5%

INTERPRETATION: The results are less than the normal range and suggest deletions of 1p and 19q in this anaplastic oligodendroglioma

[REDACTED] del (1p) and del(19q) has been observed in glioma specimens, especially oligodendrogliomas. Clinical and pathologic correlation is recommended.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

[page 5 of 5]
[REDACTED]

Data Analysis:

DESCRIPTION OF THE ASSAY: 1p and 19q FISH studies were performed on paraffin embedded tumor sections. Two hybridizations were performed: one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the Molecular Pathology Laboratory at [REDACTED]

[REDACTED].

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

Histology Laboratory
[REDACTED]

Source: NCI Genomic Data Commons file 59cab137-0335-4bfe-bfc7-838f63469be4 (TCGA-CS-5396.7AE9D388-1145-4549-91FE-0B8DC6D180FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).